Somatic mutation profile of tumor specimen TCGA-DX-A6YR-01A (aliquot TCGA-DX-A6YR-01A-33D-A351-09) from TCGA case TCGA-DX-A6YR, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 75.1 years (27,434 days).
Specimen TCGA-DX-A6YR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9565e668-48b2-4f6b-9b0b-7132d2e972f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A6YR-10B (Blood Derived Normal), aliquot TCGA-DX-A6YR-10B-01D-A351-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b810a9e9-ab88-4e0c-a687-af831b8b8d4b

The open-access MAF lists 74 somatic variants for this specimen: 50 protein-altering or splice-affecting, 20 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 20, Nonsense Mutation 5, RNA 2, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AASDHPPT | c.926C>T p.S309L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99593339; called by muse, mutect2, varscan2
- ADGRL1 | c.163G>A p.V55I | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1460816826, COSV61565050; called by muse, mutect2, varscan2
- ANK3 | c.6613C>A p.P2205T | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as COSV99780291; called by muse, mutect2, varscan2
- BCL7B | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs782735560, COSV99790320; called by muse, mutect2, varscan2
- CERKL | c.1607T>C p.V536A (on ENST00000339098 / NM_001030311.2; = p.V510A on NM_201548.5) | Missense Mutation (SNP) | VAF 85/114 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs1430540007, COSV100183776; called by muse, mutect2, varscan2
- CFAP91 | c.1814G>A p.R605H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201045322, COSV56338931; called by muse, varscan2
- CHRNA7 | c.1124C>T p.A375V | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.108); catalogued as rs374714000; called by mutect2, varscan2
- CLDN8 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV54526793; called by muse, mutect2, varscan2
- COL22A1 | c.4543G>A p.G1515S | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs931304758, COSV57330275, COSV57356553; called by muse, mutect2, varscan2
- FAT1 | c.8113G>T p.E2705* | Nonsense Mutation (SNP) | VAF 20/26 reads (77%) | catalogued as COSV71676746; called by muse, mutect2, varscan2
- FTMT | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.551); catalogued as COSV100360355; called by muse, mutect2, varscan2
- GALNT18 | c.488T>A p.V163D | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV99924778; called by muse, mutect2, varscan2
- GARRE1 | c.2615A>T p.N872I | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.246); catalogued as rs1395430795, COSV100209490; called by muse, mutect2, varscan2
- GJA8 | c.58G>A p.V20I | Missense Mutation (SNP) | VAF 36/53 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs782298787, COSV53789216; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GNPTAB | c.3686C>T p.A1229V | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100171536; called by muse, mutect2
- GPR50 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs372712912, COSV54438881, COSV99506217; called by muse, mutect2, varscan2
- HAPLN1 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1176234826, COSV57146023; called by muse, mutect2, varscan2
- HCAR2 | c.788C>T p.T263M | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.109); catalogued as rs201581105; called by muse, mutect2, varscan2
- HCN2 | c.874G>A p.V292M | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.33); catalogued as rs763669273, COSV99241877; called by muse, mutect2, varscan2
- HPSE2 | c.1495C>A p.L499I | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV100985920; called by muse, mutect2, varscan2
- HPSE2 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs373235110, COSV65184516; called by muse, mutect2, varscan2
- ITGB7 | c.2264G>A p.R755H | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs755135151, COSV99913892; called by muse, mutect2, varscan2
- ITPR2 | c.6538G>T p.V2180L | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.028); catalogued as COSV101190011; called by muse, mutect2, varscan2
- KCNG4 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs777359377, COSV57582777, COSV57585394; called by muse, varscan2
- KCNH2 | c.3400C>T p.R1134* | Nonsense Mutation (SNP) | VAF 32/60 reads (53%) | catalogued as rs965259777, CD057243, COSV51230175; called by muse, mutect2, varscan2
- LY9 | c.1229C>A p.S410* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as COSV54438070, COSV99626841; called by muse, mutect2, varscan2
- MAGEC1 | c.3391A>G p.S1131G | Missense Mutation (SNP) | VAF 45/53 reads (85%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.483); catalogued as COSV53567654, COSV53572995; called by muse, mutect2, varscan2
- MATN4 | c.1298G>A p.R433H (on ENST00000372754; = p.R392H on NM_003833.4) | Missense Mutation (SNP) | VAF 19/70 reads (27%) | PolyPhen probably damaging (0.995); catalogued as rs1016514539, COSV61352450; called by muse, mutect2, varscan2
- MMRN2 | c.123G>A p.W41* | Nonsense Mutation (SNP) | VAF 15/28 reads (54%) | catalogued as rs866222300, COSV100813825; called by muse, varscan2
- MOGAT2 | c.821T>A p.I274K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV99549597; called by muse, mutect2, varscan2
- MROH7 | c.2552T>G p.V851G | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT tolerated (0.16); PolyPhen benign (0.14); catalogued as COSV100273589; called by muse, mutect2, varscan2
- MYBPC3 | c.194C>T p.T65M | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.963); catalogued as rs753300898, COSV57030718; ClinVar: uncertain significance; called by mutect2, varscan2
- MYO18B | c.3808C>T p.R1270C | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371063606; called by muse, mutect2
- MYO1G | c.2123G>A p.R708H | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs746489100, COSV99348759; called by muse, mutect2, varscan2
- NCAPG2 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.081); catalogued as rs1396826395, COSV99317092; called by muse, mutect2, varscan2
- NXNL2 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV101018301; called by muse, mutect2, varscan2
- OR2V2 | c.75C>A p.D25E | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.978); catalogued as COSV100080145; called by muse, mutect2, varscan2
- OR6X1 | c.442G>A p.V148M | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.055); catalogued as COSV100020550; called by muse, mutect2
- PKHD1 | c.7285G>A p.V2429I | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs148284341; called by muse, mutect2, varscan2
- PPCS | c.615A>G p.I205M | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100999506; called by muse, mutect2, varscan2
- PTPN21 | c.1159G>A p.G387S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100162029; called by muse, mutect2
- RSAD1 | c.1219C>T p.R407W | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375677855; called by muse, mutect2, varscan2
- SCN8A | c.2791C>T p.R931* | Nonsense Mutation (SNP) | VAF 21/74 reads (28%) | catalogued as rs1555225831, COSV61977262; called by muse, mutect2, varscan2
- SEZ6L | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 29/243 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs996288290, COSV50662638; called by muse, mutect2, varscan2
- SHANK1 | c.1841G>A p.R614H | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs750243375, COSV99521362; called by muse, mutect2, varscan2
- SLC7A3 | c.1282C>T p.L428F | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV99979582; called by muse, mutect2, varscan2
- STAB2 | c.76G>T p.G26W | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV101186012; called by muse, mutect2, varscan2
- TRPV5 | c.334T>C p.C112R | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs367563090; called by muse, mutect2, varscan2
- UHRF1 | c.2341G>A p.V781I (on ENST00000612630 / NM_001290050.1; = p.V794I on NM_013282.4) | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV99503303; called by muse, mutect2, varscan2
- VSIR | c.233G>A p.G78D | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.709); catalogued as COSV56488961, COSV99821342; called by muse, mutect2, varscan2
- AQP12B | c.213C>T p.H71= (on ENST00000621682; = p.H83= on NM_001102467.2) | Silent (SNP) | VAF 23/109 reads (21%) | catalogued as rs373980987; called by muse, mutect2, varscan2
- CDC42EP1 | c.687A>C p.A229= | Silent (SNP) | VAF 20/49 reads (41%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.3678C>T p.S1226= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as rs201219937, COSV100667012; ClinVar: likely benign / benign / uncertain significance; called by muse, mutect2, varscan2
- FOLH1 | c.807A>C p.T269= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as COSV57054717, COSV99923298; called by muse, mutect2, varscan2
- GUCY2F | c.879C>A p.T293= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV99485098; called by muse, mutect2, varscan2
- ILVBL | c.162C>T p.G54= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs1334870342, COSV54620373; called by muse, mutect2, varscan2
- ING2 | c.183G>A p.K61= | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as COSV100180440; called by muse, mutect2, varscan2
- KLF2 | c.1050C>T p.H350= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV99934194; called by muse, mutect2, varscan2
- KLK15 | c.300G>A p.A100= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs559995592, COSV100032753; called by muse, mutect2, varscan2
- LHX5 | c.555C>A p.T185= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV99922481; called by muse, mutect2, varscan2
- MATK | c.1356C>T p.P452= (on ENST00000310132 / NM_139355.3; = p.P453= on NM_002378.4) | Silent (SNP) | VAF 61/72 reads (85%) | catalogued as rs777960362, COSV59554845; called by muse, mutect2, varscan2
- MYO5B | c.2445G>A p.A815= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as rs372848572; called by muse, mutect2, varscan2
- PCDHA6 | c.1086C>T p.D362= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV65351105; called by muse, mutect2, varscan2
- PHYKPL | c.969C>G p.V323= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100359416; called by mutect2, varscan2
- RGS3 | c.3468G>A p.T1156= (on ENST00000350696 / NM_001282923.2; = p.T875= on NM_130795.4) | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as rs1449984788, COSV59511673; called by muse, mutect2, varscan2
- TFDP1 | c.1227C>T p.D409= | Silent (SNP) | VAF 50/118 reads (42%) | catalogued as rs766724907, COSV100945896; called by muse, mutect2, varscan2
- TOX2 | c.246A>T p.T82= (on ENST00000358131 / NM_001098798.2; = p.T31= on NM_032883.3) | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV100363957; called by muse, mutect2, varscan2
- VRTN | c.249C>A p.G83= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV99832277; called by muse, mutect2, varscan2
- ZNF467 | c.693G>T p.L231= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV100117999; called by muse, mutect2, varscan2
- ZNF665 | c.1332T>C p.T444= (on ENST00000600412; = p.T509= on NM_024733.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as COSV101128445; called by muse, mutect2, varscan2
- IGHM | c.1300+30G>A | Intron (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2, varscan2
- KIR3DX1 | n.723A>C | RNA (SNP) | VAF 10/39 reads (26%) | catalogued as COSV99683367; called by muse, mutect2, varscan2
- SF1 | c.*392G>A | 3'UTR (SNP) | VAF 13/55 reads (24%) | catalogued as rs539758407, COSV99918408; called by muse, mutect2, varscan2
- SSPOP | n.2271C>T | RNA (SNP) | VAF 8/64 reads (13%) | catalogued as rs940202849, COSV100022574; called by muse, mutect2, varscan2
